Gene-level copy-number profile of tumor specimen TCGA-CQ-7067-01A from TCGA case TCGA-CQ-7067, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.9 years (27,707 days).
Specimen TCGA-CQ-7067-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.fd9c332e-392c-48e0-882a-8bf082a4f5fe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-7067-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7af03638-4fe4-4533-8fd5-38267173f169

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 3,356; copy number 2: 26,859; copy number 3: 20,364; copy number 4: 5,210; copy number 5: 2,269; copy number 6: 811; copy number 7: 129; copy number 8: 720; copy number 11: 35; copy number 17: 38; copy number 20: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CQ-7067-01): tumor purity 0.45, ploidy 2.79, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:80,679,684–80,755,621, 2 genes (within-gene range 0–5): ABHD17C, AC023302.1.
- chr15:81,000,923–81,149,179, 3 genes (within-gene range 0–5): TLNRD1, CFAP161, AC068870.3.
- chr15:81,427,448–82,046,119, 5 genes (within-gene range 0–5): AC060809.1, AC023034.1, AC104041.1, AC026956.1, MEX3B.
- chr15:93,416,850–93,431,217, 2 genes: AC091078.2, SEPHS1P2.
- chr15:94,455,469–94,589,259, 2 genes (within-gene range 0–5): AC009432.2, LINC02852.
- chr15:101,602,786–101,652,391, 2 genes (within-gene range 0–5): LINC02348, TM2D3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,009 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:59,296,638–65,067,754, 87 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:158,795,317–158,870,393, 4 genes, copy number 6 (within-gene range 2–6): DAPL1, AC064843.1, OR7E89P, OR7E28P.
- chr2:172,137,345–172,370,401, 1 gene, copy number 5 (within-gene range 2–5): AC104088.1.
- chr2:172,323,260–174,248,599, 33 genes, copy number 5–7: AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1, AC013410.2, AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P.
- chr3:142,596,393–198,222,513, 962 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr6:39,188,971–41,239,626, 35 genes, copy number 5–7: KCNK5, KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1, UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207.
- chr7:68,091,223–114,075,920, 803 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:69,641,156–71,608,040, 53 genes, copy number 6–20: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6.
- chr11:81,175,201–83,423,516, 38 genes, copy number 8–11: AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 11: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr15:49,858,238–50,182,817, 1 gene, copy number 5 (within-gene range 2–5): ATP8B4.
- chr15:49,982,443–80,597,933, 773 genes, copy number 5 (broad region; genes not listed).
- chr15:80,769,600–80,999,981, 9 genes, copy number 5: AC023302.2, CEMIP, MIR549A, AC027808.1, AC027808.2, MESD, AC068870.1, MIR4514, AC068870.2.
- chr15:81,159,575–81,518,200, 9 genes, copy number 5: IL16, AC103858.1, STARD5, AC103858.3, TMC3-AS1, TMC3, AC103858.2, KF456110.1, AC109809.1.
- chr15:82,088,569–93,569,483, 316 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr15:93,589,867–94,483,952, 13 genes, copy number 5: AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2.
- chr15:94,600,014–101,581,556, 144 genes, copy number 5 (broad region; genes not listed).
- chr15:101,648,206–101,933,350, 15 genes, copy number 5: RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.

Autosomal genes at a single copy (total copy number 1): 2,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
